Somatic mutation profile of tumor specimen TCGA-LD-A66U-01A (aliquot TCGA-LD-A66U-01A-11D-A31U-09) from TCGA case TCGA-LD-A66U, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 44.1 years (16,101 days).
Specimen TCGA-LD-A66U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22235bcb-ab50-4aff-aeba-c2baefbc63c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LD-A66U-10A (Blood Derived Normal), aliquot TCGA-LD-A66U-10A-01D-A31U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/190db2f5-707d-476c-9a61-aab0f7152631

The open-access MAF lists 25 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 18, Silent 4, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.2164+2T>G p.X722_splice | Splice Site (SNP) | VAF 7/36 reads (19%) | hotspot (GDC flag); catalogued as CS135587, COSV55737914, COSV99931611, COSV99931840; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ASCC3 | c.3011C>T p.A1004V | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.281); catalogued as COSV100225492; called by muse, mutect2, varscan2
- CHD1 | c.422G>A p.R141K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV99399292; called by muse, mutect2, varscan2
- DNAH1 | c.4208G>A p.R1403H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs764348206, COSV70227620, COSV70229232; called by muse, mutect2, varscan2
- EML5 | c.3954G>T p.M1318I | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as COSV100715331; called by muse, mutect2, varscan2
- EPHX4 | c.930G>T p.M310I | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100952663; called by muse, mutect2
- ITIH4 | c.928T>C p.F310L | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.452); catalogued as COSV99819133; called by muse, mutect2, varscan2
- KIRREL3 | c.2135A>T p.Q712L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.838); catalogued as COSV101375185; called by muse, mutect2, varscan2
- LAIR2 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.027); catalogued as rs1208260258, COSV100003205; called by muse, mutect2, varscan2
- NDUFA10 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99401318; called by muse, mutect2, varscan2
- NUP107 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs139969249; called by muse, mutect2
- OR2M5 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as COSV100822787; called by muse, mutect2, varscan2
- PATJ | c.2752C>G p.P918A | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100333688; called by muse, mutect2, varscan2
- PYGB | c.2168A>G p.D723G | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV99404984; called by muse, mutect2, varscan2
- ROCK1 | c.3146A>G p.N1049S | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as rs761438534, COSV101296307; called by muse, mutect2
- SLC22A14 | c.1738A>G p.K580E | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99828180; called by muse, mutect2
- TGFBI | c.1540C>A p.R514S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs200065806, COSV100526403; called by muse, mutect2, varscan2
- UBE2O | c.3040G>T p.A1014S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.303); catalogued as COSV100039248; called by mutect2, varscan2
- APOBR | c.3150del p.R1050Sfs*25 (on ENST00000431282; = p.R1059Sfs*25 on NM_018690.4) | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- VAV2 | c.692dup p.L232Afs*12 (on ENST00000371850 / NM_001134398.2; = p.L227Afs*12 on NM_003371.4) | Frame Shift Ins (INS) | VAF 21/100 reads (21%) | called by mutect2, pindel, varscan2
- CPXM1 | c.510C>T p.A170= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs201295871, COSV101013702; called by muse, mutect2, varscan2
- MUC5B | c.13908G>A p.T4636= | Silent (SNP) | VAF 17/147 reads (12%) | catalogued as rs559701109, COSV71595124; called by muse, mutect2, varscan2
- MXRA5 | c.849T>G p.P283= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV99476327; called by muse, mutect2, varscan2
- SCN2A | c.402C>A p.L134= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as COSV51834996; called by muse, mutect2
